Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A05D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A05D-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes
- 2: SP: Right external iliac lymph nodes
- 3: SP: Right hypogastric lymph nodes
- 4: SP: Right obturator lymph nodes
- 5: SP: Right para-aortic lymph nodes
- 6: SP: Left external iliac lymph nodes
- 7: SP: Left obturator lymph nodes
- 8: SP: Left para-aortic lymph nodes
- 9: SP: Left abdominal wall lipoma

ICD-0-3

adenocarcinoma, serous, NOS 8441/3
Site: endometrium C54.1
lw 5/2/11

DIAGNOSIS:

1. UTERUS, CERVIX, AND FALLOPIAN TUBES; HYSTERECTOMY AND BILATERAL SALPINGECTOMY:

- ADENOCARCINOMA OF ENDOMETRIUM, PAPILLARY SEROUS TYPE.
- THE TUMOR INVADES TO > HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 11 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 15 MM.

- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ATROPHY.
- THE MYOMETRIUM IS UNREMARKABLE.
- ALL ADNEXAE ARE UNREMARKABLE.

2. LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- EIGHT BENIGN LYMPH NODES (0/8).

3. LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

4. LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).

5. LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:

** Continued on next page **

Hx on Enroll
of Prior Malignancy
OK - ONE ---

Diagnostic Discrepancy		
Prior Malignancy		

lw 5/2/11

[page 2 of 2]
- FOUR BENIGN LYMPH NODES (0/4).

6. LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- ONE OUT OF NINE (1/9) LYMPH NODES POSITIVE FOR METASTATIC
CARCINOMA.

7. LYMPH NODES, LEFT OBTURATOR; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).

8. LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- ONE OUT OF FOUR (1/4) LYMPH NODES POSITIVE FOR METASTATIC
CARCINOMA.

9. SOFT TISSUE, ABDOMINAL WALL, LEFT; EXCISION:
- LIPOMA.
- BENIGN SKIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Source: NCI Genomic Data Commons file 0a5b6a7a-cc54-448a-85de-fdf85e3d94a3 (TCGA-AP-A05D.3312F531-00A3-4104-8C9C-8734C32C89C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).